Somatic mutation profile of tumor specimen TARGET-20-PASZZE-09A (aliquot TARGET-20-PASZZE-09A-02D) from TARGET case TARGET-20-PASZZE, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.9 years (3,998 days).
Specimen TARGET-20-PASZZE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16dfd7d8-ebd6-4fdd-9d10-4417dd245cbc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASZZE-14A (Bone Marrow Normal), aliquot TARGET-20-PASZZE-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64831470-3bc6-4e52-aae5-bdc5bf76197d

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 55/109 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AFDN | c.4879C>T p.R1627* (on ENST00000447894 / NM_001366320.1; = p.R1625* on NM_001040000.3) | Nonsense Mutation (SNP) | VAF 55/136 reads (40%) | catalogued as rs765916256, COSV60039991; called by muse, mutect2, varscan2
- DNAH2 | c.10327G>A p.V3443M | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs531676332, COSV66722659; called by muse, mutect2, varscan2
- FAT1 | c.9157C>T p.R3053C | Missense Mutation (SNP) | VAF 75/250 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs367986355; called by muse, mutect2, varscan2
- LAMA1 | c.4300T>G p.C1434G | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67541623; called by muse, mutect2, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by muse, varscan2
- PHF6 | c.834+1_834+2insCCCCAGGAAAAAGAATGG | In Frame Ins (INS) | VAF 30/47 reads (64%) | called by mutect2, varscan2
